Somatic mutation profile of tumor specimen TCGA-5C-AAPD-01A (aliquot TCGA-5C-AAPD-01A-21D-A38X-10) from TCGA case TCGA-5C-AAPD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 61.7 years (22,552 days).
Specimen TCGA-5C-AAPD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24d20fc9-4503-4bc5-b093-1b08e7d23602.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5C-AAPD-10A (Blood Derived Normal), aliquot TCGA-5C-AAPD-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75a93ebd-dd23-49f0-a50d-3a6510e9dee5

The open-access MAF lists 76 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 17, Splice Site 5, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF2 | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV100904076; called by muse, mutect2, varscan2
- ASB10 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99318291; called by muse, mutect2, varscan2
- ASS1 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.433); catalogued as COSV100752539; called by muse, mutect2, varscan2
- ATG2B | c.6171G>T p.M2057I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99951961; called by muse, mutect2, varscan2
- ATL1 | c.532T>G p.L178V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100612942; called by muse, mutect2, varscan2
- BRAP | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as rs756787438, COSV100553995; called by muse, mutect2, varscan2
- CAPN11 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | catalogued as COSV101291853; called by muse, mutect2, varscan2
- CDH17 | c.1807A>T p.R603W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs558415835, COSV99217025; called by muse, mutect2, varscan2
- CFAP43 | c.3187C>A p.Q1063K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.318); catalogued as COSV99530448; called by muse, mutect2, varscan2
- COL2A1 | c.3887-1G>A p.X1296_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100475729; called by muse, mutect2, varscan2
- DAGLB | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.15); catalogued as rs1414035654, COSV99765702; called by muse, mutect2, varscan2
- EEF1G | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs1179848229, COSV100240185; called by muse, mutect2, varscan2
- GOLGA3 | c.3367G>A p.G1123S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99202316; called by muse, mutect2, varscan2
- HECTD4 | c.8527G>C p.V2843L | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.969); catalogued as COSV101106873; called by muse, mutect2, varscan2
- HNRNPUL2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1464008833, COSV99584559; called by muse, mutect2, varscan2
- HOXA10 | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99385314; called by muse, mutect2, varscan2
- HSD17B6 | c.817A>C p.T273P | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100444222; called by muse, mutect2, varscan2
- KCNJ10 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as COSV63634993; called by muse, mutect2, varscan2
- KISS1 | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100916403; called by muse, mutect2, varscan2
- LRP1B | c.3369A>T p.E1123D | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV101253733; called by muse, mutect2, varscan2
- MAVS | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.058); catalogued as COSV100816263; called by muse, mutect2, varscan2
- NSD2 | c.3019A>G p.T1007A | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100372920; called by muse, mutect2, varscan2
- OR2D2 | c.317T>A p.I106N | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.391); catalogued as COSV100203749, COSV55057435; called by muse, mutect2, varscan2
- PCDHA12 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 36/97 reads (37%) | catalogued as COSV100248347, COSV56482589; called by muse, mutect2, varscan2
- PHF3 | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 114/451 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012974; called by muse, mutect2, varscan2
- RASSF9 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100771243; called by muse, mutect2, varscan2
- RB1 | c.2167del p.I723Sfs*3 | Frame Shift Del (DEL) | VAF 222/354 reads (63%) | catalogued as CM030514; called by mutect2, varscan2
- RIMBP3 | c.2680G>A p.V894M | Missense Mutation (SNP) | VAF 60/513 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs781768696; called by muse, mutect2, varscan2
- RIOX1 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV58374416; called by muse, mutect2, varscan2
- SLC25A12 | c.1391C>A p.P464H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV99784751; called by muse, mutect2, varscan2
- SLC25A14 | c.936+1G>T p.X312_splice | Splice Site (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99502326; called by muse, mutect2
- SNX31 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61263438; called by mutect2, varscan2
- SPATS2 | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100423397; called by muse, mutect2, varscan2
- SYDE1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99654626; called by muse, mutect2, varscan2
- TLK2 | c.1820G>T p.G607V (on ENST00000326270 / NM_001284333.2; = p.G585V on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408793, COSV100409030; called by muse, mutect2, varscan2
- TLR6 | c.1974T>A p.S658R | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV101126245; called by muse, mutect2, varscan2
- TNFAIP6 | c.773dup p.N258Kfs*10 | Frame Shift Ins (INS) | VAF 31/157 reads (20%) | catalogued as rs759969484; called by mutect2, pindel, varscan2
- TNNT3 | c.17+1G>T p.X6_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99547996; called by muse, mutect2
- TP53 | c.128del p.L43* | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | catalogued as COSV52992944; called by mutect2, pindel, varscan2
- TP73 | c.186+1G>A p.X62_splice | Splice Site (SNP) | VAF 53/153 reads (35%) | catalogued as COSV100601002; called by muse, mutect2, varscan2
- TRMT6 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.07); catalogued as COSV99177519; called by muse, mutect2, varscan2
- TRMU | c.114C>A p.N38K | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324471; called by muse, mutect2, varscan2
- TRPM6 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100665652; called by muse, mutect2, varscan2
- VIT | c.1940A>C p.H647P (on ENST00000389975 / NM_001177969.1; = p.H662P on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101007212; called by muse, mutect2, varscan2
- WDR38 | c.143G>A p.W48* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100793801; called by muse, mutect2
- WDR47 | c.1475G>T p.G492V (on ENST00000369962 / NM_001142551.2; = p.G493V on NM_014969.5) | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100728254; called by muse, mutect2, varscan2
- WDR90 | c.937A>C p.S313R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99552839; called by muse, mutect2, varscan2
- ZBED9 | c.3885A>C p.L1295F | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101509149; called by muse, mutect2, varscan2
- ZNF236 | c.4814T>C p.L1605P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778910367, COSV99469409; called by muse, mutect2, varscan2
- ZNF396 | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.87); catalogued as COSV100108487; called by muse, mutect2, varscan2
- ZNF423 | c.1753A>T p.I585F (on ENST00000563137 / NM_001379286.1; = p.I577F on NM_015069.4) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as COSV99280320; called by muse, mutect2, varscan2
- ZNF441 | c.1209C>G p.F403L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100777402, COSV63539159, COSV63539281; called by muse, mutect2, varscan2
- ZNF781 | c.355T>C p.C119R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs993301793, COSV100669135; called by muse, mutect2, varscan2
- ARSD | c.1190_1212del p.H397Rfs*32 | Frame Shift Del (DEL) | VAF 188/312 reads (60%) | called by mutect2, pindel, varscan2
- DHX57 | c.3388-2_3412del p.X1130_splice | Splice Site (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- IL23R | c.578dup p.L193Ffs*24 | Frame Shift Ins (INS) | VAF 75/300 reads (25%) | called by mutect2, pindel, varscan2
- RALGPS1 | c.572del p.I191Tfs*4 | Frame Shift Del (DEL) | VAF 25/97 reads (26%) | called by mutect2, pindel, varscan2
- RERE | c.4391_4393del p.H1464del | In Frame Del (DEL) | VAF 47/162 reads (29%) | called by mutect2, pindel, varscan2
- AKAP3 | c.1947C>A p.A649= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV99961860; called by muse, mutect2, varscan2
- APCDD1 | c.606G>A p.V202= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as COSV100789908; called by muse, mutect2, varscan2
- FCRL1 | c.483G>A p.Q161= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV100839733; called by muse, mutect2, varscan2
- GUCA1A | c.318C>T p.C106= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1270658005, COSV99273851; called by muse, mutect2, varscan2
- IFT172 | c.3699C>T p.L1233= | Silent (SNP) | VAF 38/145 reads (26%) | catalogued as rs773641257, COSV99561950; called by muse, mutect2, varscan2
- IQGAP3 | c.1779C>T p.R593= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs1374114888, COSV100752090; called by muse, mutect2, varscan2
- MACROD1 | c.672C>A p.I224= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99734776; called by muse, mutect2, varscan2
- MAP1S | c.1041G>T p.R347= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1279392021, COSV100140876; called by muse, mutect2, varscan2
- MEGF6 | c.2547C>G p.P849= | Silent (SNP) | VAF 107/239 reads (45%) | catalogued as COSV53888956, COSV99619649; called by muse, mutect2, varscan2
- MYO18B | c.5964A>G p.R1988= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV100122836; called by muse, mutect2, varscan2
- NBAS | c.843G>A p.P281= | Silent (SNP) | VAF 61/219 reads (28%) | catalogued as rs746249157, COSV99867787; called by muse, mutect2, varscan2
- PUM2 | c.1176G>A p.Q392= | Silent (SNP) | VAF 40/163 reads (25%) | catalogued as rs748049050, COSV100163272; called by muse, mutect2, varscan2
- RIBC1 | c.1122T>C p.F374= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as COSV51447872, COSV99394881; called by muse, mutect2, varscan2
- STYXL2 | c.963C>A p.A321= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV99608715; called by muse, mutect2, varscan2
- TEX2 | c.2319T>G p.L773= (on ENST00000583097 / NM_001288733.2; = p.L780= on NM_018469.5) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99366853; called by muse, mutect2, varscan2
- TUFT1 | c.666G>T p.V222= | Silent (SNP) | VAF 83/364 reads (23%) | catalogued as COSV100777029; called by muse, mutect2, varscan2
- WDR47 | c.1476C>G p.G492= (on ENST00000369962 / NM_001142551.2; = p.G493= on NM_014969.5) | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV100728253; called by muse, mutect2, varscan2
- VEGFA | chr6:43771124 GCCCGGGCCTCGGGCC>A | 5'Flank (DEL) | VAF 27/61 reads (44%) | called by pindel, varscan2*
